Somatic mutation profile of tumor specimen TCGA-BJ-A18Y-01A (aliquot TCGA-BJ-A18Y-01A-11D-A13W-08) from TCGA case TCGA-BJ-A18Y, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 29.7 years (10,832 days).
Specimen TCGA-BJ-A18Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e34c8b26-447f-4a62-bfb9-0522d1396a9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A18Y-10A (Blood Derived Normal), aliquot TCGA-BJ-A18Y-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53a79a7d-89b9-45bf-bce2-0f6c62fb0170

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 55/178 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANGPTL2 | c.416T>A p.M139K | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV52221159; called by muse, mutect2
- CYB5R4 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs761338251, COSV63746465, COSV63746836; called by muse, mutect2, varscan2
- PRSS38 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64540303; called by muse, mutect2
- RRP9 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288640186, COSV51754131; called by muse, mutect2, varscan2
- MFSD2B | c.927A>G p.T309= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV57854623; called by muse, mutect2, varscan2
- TG | c.2037C>T p.G679= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV55074270; called by muse, mutect2, varscan2
